Somatic mutation profile of tumor specimen MMRF_2764_1_BM_CD138pos (aliquot MMRF_2764_1_BM_CD138pos_T1_KHS5U_L15716) from MMRF case MMRF_2764, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 56.3 years (20,546 days).
Specimen MMRF_2764_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f08b4f84-7c3b-417d-9fa9-f7b5c55d341d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2764_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2764_1_PB_WBC_C3_KHS5U_L15760; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6335aed2-979e-4a67-b17a-237d0f8cb366

The open-access MAF lists 152 somatic variants for this specimen: 57 protein-altering or splice-affecting, 19 silent, 76 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, 3'UTR 45, Silent 19, Intron 16, 5'UTR 7, 5'Flank 4, Splice Site 3, 3'Flank 2, Nonsense Mutation 2, Frame Shift Del 2, RNA 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CA12 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 33/196 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs745416558, COSV51606493; called by muse, mutect2, varscan2
- CARD11 | c.1285G>C p.V429L | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.11); catalogued as COSV67802261; called by muse, mutect2
- EME1 | c.1684C>T p.P562S | Missense Mutation (SNP) | VAF 65/278 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs756425292; called by muse, mutect2, varscan2
- GP5 | c.140G>A p.G47D | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.037); catalogued as COSV55468311; called by muse, mutect2, varscan2
- IGLV4-60 | c.150T>A p.S50R | Missense Mutation (SNP) | VAF 84/104 reads (81%) | SIFT deleterious (0.03); PolyPhen benign (0.234); catalogued as rs778959737; called by muse, varscan2
- IGLV7-46 | c.340A>G p.S114G | Missense Mutation (SNP) | VAF 37/38 reads (97%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs555164835; called by muse, mutect2, varscan2
- JUNB | c.560G>A p.S187N | Missense Mutation (SNP) | VAF 279/459 reads (61%) | SIFT tolerated (0.42); PolyPhen benign (0.03); catalogued as rs1483236669; called by muse, mutect2, varscan2
- MDN1 | c.12896T>G p.I4299S | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as COSV65530548; called by muse, mutect2, varscan2
- METTL9 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375496896; called by muse, mutect2, varscan2
- MUC16 | c.4510G>C p.A1504P | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.632); catalogued as COSV67486979; called by muse, mutect2
- PHF19 | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 47/87 reads (54%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1308378582; called by muse, mutect2, varscan2
- PKLR | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.857); catalogued as rs1275173660; called by muse, mutect2, varscan2
- PPP1R16B | c.724C>A p.L242M | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.324); catalogued as COSV100239276, COSV100239310; called by muse, mutect2, varscan2
- RTN2 | c.673C>T p.R225* | Nonsense Mutation (SNP) | VAF 71/368 reads (19%) | catalogued as COSV55592970; called by muse, mutect2, varscan2
- SEMA3E | c.1264C>A p.P422T | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762609959, COSV57112765; called by muse, mutect2, varscan2
- TSHZ3 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 117/357 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs772620837, COSV53674551; called by muse, mutect2, varscan2
- UFL1 | c.287G>A p.R96K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.264); catalogued as COSV65150100; called by muse, mutect2, varscan2
- XPOT | c.1025A>T p.D342V | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60344547; called by muse, mutect2, varscan2
- ZFHX4 | c.1966C>T p.Q656* | Nonsense Mutation (SNP) | VAF 54/111 reads (49%) | catalogued as COSV51484597; called by muse, mutect2, varscan2
- ZNF106 | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 186/415 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.118); catalogued as rs201738274; called by muse, mutect2, varscan2
- ZNF546 | c.1784A>C p.N595T | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.072); catalogued as COSV100713555, COSV61258194; called by muse, mutect2, varscan2
- AKAP9 | c.5372G>T p.R1791I (on ENST00000359028; = p.R1759I on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/253 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- ARIH1 | c.1432_1434dup p.F478dup | In Frame Ins (INS) | VAF 29/236 reads (12%) | called by mutect2, pindel, varscan2
- CENPB | c.1406A>C p.E469A | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- CHRM2 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 24/271 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.823); called by muse, mutect2
- CPE | c.1193T>G p.I398R | Missense Mutation (SNP) | VAF 79/173 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- CYLD | c.1239_1248del p.E413Dfs*30 | Frame Shift Del (DEL) | VAF 24/49 reads (49%) | called by mutect2, pindel, varscan2
- DAPK3 | c.1193A>T p.E398V | Missense Mutation (SNP) | VAF 106/152 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- DUSP8 | c.407T>C p.L136P | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- EML6 | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FAT4 | c.1057G>T p.V353L | Missense Mutation (SNP) | VAF 143/287 reads (50%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- FBXL19 | c.1094A>G p.E365G | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- FGF2 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- HCRTR2 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 32/262 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- IGLV5-45 | c.326A>C p.D109A | Missense Mutation (SNP) | VAF 83/97 reads (86%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- IGLV7-46 | c.223A>G p.K75E | Missense Mutation (SNP) | VAF 44/48 reads (92%) | SIFT deleterious (0); PolyPhen benign (0.143); called by muse, mutect2
- INTS12 | c.1151A>G p.K384R | Missense Mutation (SNP) | VAF 72/251 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- IRF1 | c.545-8T>A | Splice Region (SNP) | VAF 30/294 reads (10%) | called by muse, mutect2
- KIAA1109 | c.10231G>T p.G3411W | Missense Mutation (SNP) | VAF 44/173 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- KIAA1109 | c.10232G>C p.G3411A | Missense Mutation (SNP) | VAF 45/175 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRTM2 | c.711G>C p.K237N | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2
- LUC7L2 | c.1126G>A p.G376S | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- MAML3 | c.1783A>G p.N595D | Missense Mutation (SNP) | VAF 104/202 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MAP4K5 | c.2326+2T>A p.X776_splice | Splice Site (SNP) | VAF 14/61 reads (23%) | called by muse, mutect2, varscan2
- NBN | c.2170del p.R724Gfs*27 | Frame Shift Del (DEL) | VAF 52/127 reads (41%) | called by mutect2, pindel, varscan2
- NLRP2 | c.2075G>A p.C692Y | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- OBSCN | c.18806C>T p.S6269F | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PIP5K1A | c.1033C>A p.Q345K (on ENST00000368888 / NM_001135638.2; = p.Q332K on NM_003557.3) | Missense Mutation (SNP) | VAF 90/214 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PTTG1 | c.276+2T>A p.X92_splice | Splice Site (SNP) | VAF 95/292 reads (33%) | called by muse, mutect2, varscan2
- RAB6B | c.125A>T p.Y42F | Missense Mutation (SNP) | VAF 48/406 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- RWDD2A | c.221T>G p.V74G | Missense Mutation (SNP) | VAF 8/137 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- SELL | c.877A>G p.S293G (on ENST00000650983; = p.S280G on NM_000655.5) | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SERINC4 | c.1432C>T p.L478F | Missense Mutation (SNP) | VAF 75/154 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- TLN2 | c.2512G>A p.D838N | Missense Mutation (SNP) | VAF 9/167 reads (5%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.968); called by muse, mutect2
- TRIM36 | c.158G>A p.C53Y | Missense Mutation (SNP) | VAF 128/216 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UTP20 | c.3561+1G>A p.X1187_splice | Splice Site (SNP) | VAF 21/179 reads (12%) | called by muse, mutect2, varscan2
- ZYX | c.1593C>G p.H531Q | Missense Mutation (SNP) | VAF 47/241 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- ADAMTS9 | c.2934T>C p.G978= | Silent (SNP) | VAF 13/71 reads (18%) | called by muse, mutect2, varscan2
- ATP8A2 | c.2277C>T p.D759= | Silent (SNP) | VAF 31/34 reads (91%) | catalogued as rs538134208; called by muse, mutect2, varscan2
- C4orf54 | c.2610C>T p.S870= | Silent (SNP) | VAF 19/136 reads (14%) | catalogued as COSV72766763; called by muse, mutect2, varscan2
- CADPS | c.1086C>T p.G362= | Silent (SNP) | VAF 21/139 reads (15%) | catalogued as rs772882768, COSV51890773; called by muse, mutect2, varscan2
- DNAH5 | c.603C>T p.S201= | Silent (SNP) | VAF 16/145 reads (11%) | catalogued as rs935006138; called by muse, mutect2, varscan2
- EVC2 | c.2247C>T p.D749= | Silent (SNP) | VAF 19/136 reads (14%) | catalogued as rs748420448, COSV60397924; ClinVar: likely benign; called by muse, mutect2, varscan2
- FBN2 | c.4422C>T p.C1474= | Silent (SNP) | VAF 16/139 reads (12%) | catalogued as rs371629482, COSV52500874, COSV99330174; called by muse, mutect2, varscan2
- H2BC13 | c.136C>T p.L46= | Silent (SNP) | VAF 96/221 reads (43%) | called by muse, mutect2, varscan2
- HRG | c.1443A>C p.P481= | Silent (SNP) | VAF 89/190 reads (47%) | called by muse, mutect2, varscan2
- IGHD1-1 | c.16A>T p.*6= | Silent (SNP) | VAF 22/23 reads (96%) | called by muse, mutect2, varscan2
- IGLV7-46 | c.225A>G p.K75= | Silent (SNP) | VAF 44/48 reads (92%) | catalogued as rs373728673; called by muse, mutect2
- MRC2 | c.2331C>T p.H777= | Silent (SNP) | VAF 19/133 reads (14%) | catalogued as COSV57645145; called by muse, mutect2, varscan2
- MYO7A | c.4920C>T p.G1640= | Silent (SNP) | VAF 121/188 reads (64%) | catalogued as rs372882699, COSV68683262; called by muse, mutect2, varscan2
- NELFB | c.1044C>T p.D348= | Silent (SNP) | VAF 16/115 reads (14%) | called by muse, mutect2, varscan2
- OR14A2 | c.222T>C p.V74= | Silent (SNP) | VAF 32/196 reads (16%) | called by muse, mutect2, varscan2
- PCDHB16 | c.625A>C p.R209= | Silent (SNP) | VAF 21/235 reads (9%) | called by muse, mutect2
- PIH1D1 | c.246C>T p.T82= | Silent (SNP) | VAF 22/158 reads (14%) | catalogued as rs778020414; called by muse, mutect2, varscan2
- PLK3 | c.1101G>A p.E367= | Silent (SNP) | VAF 90/185 reads (49%) | catalogued as rs1295343451; called by muse, mutect2, varscan2
- ZNF112 | c.2523C>G p.G841= (on ENST00000337401 / NM_001083335.2; = p.G835= on NM_013380.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 39/243 reads (16%) | called by muse, mutect2, varscan2
- ABR | c.700+380del | Intron (DEL) | VAF 9/75 reads (12%) | called by mutect2, pindel
- AC011503.1 | n.467+7336C>T | Intron (SNP) | VAF 64/423 reads (15%) | called by muse, mutect2, varscan2
- ADAM12 | c.*2747G>A | 3'UTR (SNP) | VAF 13/57 reads (23%) | catalogued as rs1261779137; called by muse, mutect2, varscan2
- ADAMTS17 | c.*1303G>T | 3'UTR (SNP) | VAF 21/159 reads (13%) | called by muse, mutect2
- ADD3 | c.*284C>T | 3'UTR (SNP) | VAF 10/48 reads (21%) | called by muse, mutect2
- AMOTL1 | c.*2039G>T | 3'UTR (SNP) | VAF 21/125 reads (17%) | catalogued as rs568994484; called by muse, mutect2, varscan2
- ARFGEF3 | c.*2385C>T | 3'UTR (SNP) | VAF 14/42 reads (33%) | called by muse, mutect2
- ASF1A | c.*353A>G | 3'UTR (SNP) | VAF 29/92 reads (32%) | catalogued as rs745635887; called by muse, mutect2, varscan2
- ATP10D | c.*1511T>C | 3'UTR (SNP) | VAF 47/100 reads (47%) | called by muse, mutect2, varscan2
- ATRNL1 | c.*964_*988del | 3'UTR (DEL) | VAF 24/93 reads (26%) | called by mutect2, pindel
- B4GALT4 | c.*517A>T | 3'UTR (SNP) | VAF 37/301 reads (12%) | called by muse, mutect2, varscan2
- BCL11A | c.-274_-271del | 5'UTR (DEL) | VAF 3/42 reads (7%) | called by mutect2, pindel*
- BCLAF3 | chrX:19912946 C>A | 3'Flank (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2, varscan2
- BTG2 | c.*546A>T | 3'UTR (SNP) | VAF 28/79 reads (35%) | called by muse, mutect2, varscan2
- CABP1 | c.*356G>A | 3'UTR (SNP) | VAF 25/143 reads (17%) | called by muse, mutect2, varscan2
- CCDC171 | c.*400A>G | 3'UTR (SNP) | VAF 11/104 reads (11%) | catalogued as rs1055368646; called by muse, mutect2, varscan2
- CCDC88A | c.-723T>C | 5'UTR (SNP) | VAF 95/184 reads (52%) | called by muse, mutect2, varscan2
- CD164 | c.175+655dup | Intron (INS) | VAF 38/263 reads (14%) | called by mutect2, pindel, varscan2
- CDRT15L2 | c.*79G>C | 3'UTR (SNP) | VAF 8/60 reads (13%) | called by muse, mutect2, varscan2
- CEP170 | c.1843+302T>A | Intron (SNP) | VAF 5/18 reads (28%) | catalogued as rs2789178; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.-364T>A | 5'UTR (SNP) | VAF 41/324 reads (13%) | called by muse, mutect2, varscan2
- CHIT1 | c.*155C>T | 3'UTR (SNP) | VAF 15/59 reads (25%) | called by muse, mutect2, varscan2
- CNKSR2 | c.1904+93T>A | Intron (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2, varscan2
- CYBC1 | c.-19G>A | 5'UTR (SNP) | VAF 17/62 reads (27%) | called by muse, mutect2, varscan2
- CYCS | c.*1785C>T | 3'UTR (SNP) | VAF 10/46 reads (22%) | called by muse, mutect2, varscan2
- EIF4A1 | c.1077-29T>G | Intron (SNP) | VAF 36/247 reads (15%) | called by muse, mutect2, varscan2
- ELOVL2 | c.*1670G>A | 3'UTR (SNP) | VAF 18/120 reads (15%) | called by muse, mutect2
- EPC2 | c.-64_-61delinsGAGGACT | 5'UTR (INS) | VAF 17/35 reads (49%) | called by pindel, varscan2*
- EXOC6B | c.1980+1045A>C | Intron (SNP) | VAF 32/54 reads (59%) | catalogued as rs1371628938; called by muse, mutect2, varscan2
- EYA1 | c.34-47174C>A | Intron (SNP) | VAF 7/50 reads (14%) | called by muse, mutect2, varscan2
- F13A1 | c.*284C>A | 3'UTR (SNP) | VAF 9/46 reads (20%) | called by muse, mutect2, varscan2
- FBXO41 | c.*1538A>G | 3'UTR (SNP) | VAF 48/137 reads (35%) | catalogued as rs1180413614; called by muse, mutect2, varscan2
- FIGN | c.*5139T>A | 3'UTR (SNP) | VAF 50/123 reads (41%) | called by muse, mutect2, varscan2
- FKBP1C | c.*569G>C | 3'UTR (SNP) | VAF 64/157 reads (41%) | called by muse, mutect2, varscan2
- FOLH1 | c.119-670A>C | Intron (SNP) | VAF 297/453 reads (66%) | called by muse, mutect2, varscan2
- GCNT1 | c.*722dup | 3'UTR (INS) | VAF 12/50 reads (24%) | catalogued as rs1217162695; called by mutect2, varscan2
- GORAB | c.*772C>T | 3'UTR (SNP) | VAF 27/72 reads (38%) | called by muse, mutect2, varscan2
- GPR27 | c.*357G>T | 3'UTR (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
- HRH4 | c.*1117del | 3'UTR (DEL) | VAF 6/19 reads (32%) | catalogued as rs1232166007; called by mutect2, varscan2
- ICE2 | chr15:60479148 A>C | 5'Flank (SNP) | VAF 91/176 reads (52%) | called by muse, mutect2, varscan2
- IGDCC3 | c.*1541G>A | 3'UTR (SNP) | VAF 14/102 reads (14%) | catalogued as rs920525349; called by muse, mutect2, varscan2
- LINC00479 | n.794del | RNA (DEL) | VAF 13/108 reads (12%) | called by mutect2, pindel
- MAP7 | c.*1464A>G | 3'UTR (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- MED20 | c.*1029T>C | 3'UTR (SNP) | VAF 39/103 reads (38%) | called by muse, mutect2, varscan2
- METTL15 | c.*715A>T | 3'UTR (SNP) | VAF 18/90 reads (20%) | called by muse, mutect2, varscan2
- MINDY2 | c.*7098G>A | 3'UTR (SNP) | VAF 20/150 reads (13%) | called by muse, mutect2, varscan2
- MTMR7 | chr8:17413363 G>A | 5'Flank (SNP) | VAF 11/15 reads (73%) | called by muse, mutect2, varscan2
- MYL12A | c.344-114A>C | Intron (SNP) | VAF 26/69 reads (38%) | called by muse, mutect2
- NKD1 | c.259+36C>T | Intron (SNP) | VAF 8/21 reads (38%) | catalogued as rs114714120; called by muse, mutect2, varscan2
- NPRL2 | c.78+30G>C | Intron (SNP) | VAF 61/209 reads (29%) | called by muse, mutect2, varscan2
- NRXN1 | c.*2252del | 3'UTR (DEL) | VAF 20/64 reads (31%) | called by mutect2, varscan2
- PCMTD1 | c.-40T>C | 5'UTR (SNP) | VAF 135/143 reads (94%) | catalogued as rs1173093971; called by muse, varscan2
- PELI1 | c.*405T>C | 3'UTR (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- POLR1A | chr2:86105942 del G | 5'Flank (DEL) | VAF 44/176 reads (25%) | catalogued as rs752291237; called by mutect2, varscan2
- RHOT1 | chr17:32141976 A>G | 5'Flank (SNP) | VAF 42/82 reads (51%) | called by muse, mutect2, varscan2
- RNF150 | c.-149G>A | 5'UTR (SNP) | VAF 20/131 reads (15%) | called by muse, mutect2, varscan2
- RORA | c.*5973C>T | 3'UTR (SNP) | VAF 18/272 reads (7%) | called by muse, mutect2
- SLAMF8 | chr1:159838025 C>T | 3'Flank (SNP) | VAF 53/183 reads (29%) | called by muse, mutect2, varscan2
- SLC6A11 | c.*2064dup | 3'UTR (INS) | VAF 20/102 reads (20%) | called by mutect2, pindel
- SPATA31D5P | n.345T>C | RNA (SNP) | VAF 22/205 reads (11%) | called by muse, mutect2, varscan2
- STEAP4 | c.*3831C>G | 3'UTR (SNP) | VAF 17/68 reads (25%) | called by muse, mutect2, varscan2
- STPG2 | c.*1030A>G | 3'UTR (SNP) | VAF 37/119 reads (31%) | called by muse, mutect2, varscan2
- SULT1A1 | c.149-9C>T | Intron (SNP) | VAF 24/172 reads (14%) | catalogued as rs1254153997; called by muse, mutect2, varscan2
- SULT1A2 | c.-5+322A>G | Intron (SNP) | VAF 7/67 reads (10%) | called by muse, mutect2, varscan2
- SYT13 | c.*2780T>A | 3'UTR (SNP) | VAF 42/181 reads (23%) | called by muse, mutect2, varscan2
- TDRKH | c.*205C>G | 3'UTR (SNP) | VAF 19/117 reads (16%) | called by muse, mutect2, varscan2
- TENM3 | c.*1095dup | 3'UTR (INS) | VAF 23/76 reads (30%) | catalogued as rs1263348724; called by mutect2, pindel, varscan2
- TM4SF20 | c.*1494A>G | 3'UTR (SNP) | VAF 42/87 reads (48%) | called by muse, mutect2, varscan2
- TMEM167A | c.*680T>G | 3'UTR (SNP) | VAF 26/133 reads (20%) | called by muse, mutect2, varscan2
- TMPPE | c.*2227C>T | 3'UTR (SNP) | VAF 18/70 reads (26%) | catalogued as rs1258171189; called by muse, mutect2, varscan2
- TNRC6A | c.4831+27C>A | Intron (SNP) | VAF 42/159 reads (26%) | called by muse, mutect2, varscan2
- TRIM5 | c.*195G>A | 3'UTR (SNP) | VAF 25/108 reads (23%) | called by muse, mutect2, varscan2
- WDR33 | c.725-9097_725-9092del | Intron (DEL) | VAF 13/79 reads (16%) | called by mutect2, pindel, varscan2
- XYLT1 | c.*1232T>G | 3'UTR (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- ZBTB39 | c.*1690C>G | 3'UTR (SNP) | VAF 19/108 reads (18%) | called by muse, mutect2, varscan2
- ZNF747 | c.*2677C>T | 3'UTR (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
